Gene-level copy-number profile of tumor specimen SM-JU32S from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen SM-JU32S: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb4669e8-5598-4909-916e-d72ebbe105a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105277 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/b8d03cee-cb5a-40cd-99a6-79834f9ff6fc

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 195; copy number 1: 25,421; copy number 2: 25,931; copy number 3: 5,398; copy number 4: 1,381; copy number 5: 48; copy number 6: 15.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:161,581,339–161,678,654, 6 genes (within-gene range 0–2): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:125,265,528–125,265,651, 1 gene: HMGB1P22.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:108,871,128–109,063,417, 1 gene: AC104248.1.
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:14,921,337–15,019,729, 2 genes (within-gene range 0–1): LDHAP4, AL592293.1.
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr11:4,278,705–4,288,083, 2 genes: SSU72P6, SSU72P4.
- chr15:41,284,007–41,380,996, 1 gene (within-gene range 0–1): AC087721.2.
- chr15:41,320,794–43,868,412, 106 genes (within-gene range 0–1) (broad region; genes not listed).
- chr15:43,875,849–43,876,244, 1 gene (within-gene range 0–1): PIN4P1.
- chr15:101,270,817–101,979,093, 35 genes: SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr17:46,372,855–46,579,691, 6 genes: NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr18:7,741,310–7,754,831, 1 gene (within-gene range 0–1): AP000897.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,724 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,985,692–121,398,806, 14 genes, copy number 3 (within-gene range 2–3): AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1.
- chr1:150,926,263–154,155,116, 192 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr1:154,193,665–158,579,899, 205 genes, copy number 3 (broad region; genes not listed).
- chr1:184,171,714–184,629,019, 7 genes, copy number 3 (within-gene range 2–3): Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1.
- chr1:224,717,504–240,612,155, 349 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr1:243,029,512–248,527,337, 156 genes, copy number 3–5 (broad region; genes not listed).
- chr1:248,649,838–248,937,043, 16 genes, copy number 5: OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:38,814–16,333,978, 245 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr2:38,073,447–39,229,588, 36 genes, copy number 3 (within-gene range 2–3): CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4.
- chr2:47,989,625–65,432,637, 258 genes, copy number 3–4 (broad region; genes not listed).
- chr2:72,887,382–73,981,441, 33 genes, copy number 3: SPR, EMX1, AC012366.1, SFXN5, RAB11FIP5, AC010913.1, NOTO, SMYD5, PRADC1, CCT7, FBXO41, EGR4, RNU6-111P, AC074008.2, RPSAP28, ALMS1, ALMS1-IT1, AC074008.1, NAT8, ALMS1P1, NAT8B, TPRKB, AC092653.1, AC092653.2, DUSP11, C2orf78, STAMBP, AC073046.3, AC073046.2, ACTG2, DGUOK, DGUOK-AS1, RNA5SP97.
- chr2:119,429,901–119,984,899, 7 genes, copy number 3: TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4.
- chr2:127,388,184–128,318,868, 32 genes, copy number 3 (within-gene range 2–3): MAP3K2-DT, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P, MYO7B, AC010976.2, LIMS2, GPR17, WDR33, SFT2D3, RNY4P7, Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1.
- chr2:228,475,224–242,175,634, 322 genes, copy number 3–5 (within-gene range 3–6) (broad region; genes not listed).
- chr3:128,153,481–133,491,505, 122 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:184,299,198–193,766,003, 154 genes, copy number 3–4 (broad region; genes not listed).
- chr4:54,229,280–70,482,997, 243 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:105,919–909,006, 19 genes, copy number 3: OR4F1P, CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1.
- chr6:33,004,182–33,927,631, 60 genes, copy number 3: HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P, LYPLA2P1, RPL35AP4, KIFC1, RPL12P1, PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9, GGNBP1, RN7SL26P, Metazoa_SRP, BAK1, LINC00336, ITPR3, UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3, LINC01016, AL138889.2, AL138889.1, MIR7159.
- chr6:104,687,241–109,483,219, 101 genes, copy number 3–4 (broad region; genes not listed).
- chr7:37,032–21,028,813, 329 genes, copy number 3–5 (broad region; genes not listed).
- chr7:27,092,993–73,865,890, 895 genes, copy number 3–6 (broad region; genes not listed).
- chr8:30,131,671–43,674,591, 264 genes, copy number 3 (broad region; genes not listed).
- chr8:47,089,572–93,029,839, 652 genes, copy number 3 (broad region; genes not listed).
- chr8:143,366,631–145,066,685, 118 genes, copy number 3–4 (broad region; genes not listed).
- chr9:35,658,290–36,163,913, 35 genes, copy number 3: CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2.
- chr9:39,631,046–40,806,344, 37 genes, copy number 3: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1.
- chr9:61,789,143–63,385,117, 49 genes, copy number 3: RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:65,287,914–107,171,148, 665 genes, copy number 3–5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:15,778,170–18,940,953, 42 genes, copy number 3: MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1.
- chr10:21,340,233–21,526,368, 8 genes, copy number 3: LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1.
- chr11:75,335,092–85,811,159, 166 genes, copy number 3 (broad region; genes not listed).
- chr11:99,020,949–104,164,379, 68 genes, copy number 3 (broad region; genes not listed).
- chr11:106,051,098–108,940,927, 40 genes, copy number 3–5: KBTBD3, AASDHPPT, AP001001.1, LINC02719, AP002001.3, AP002001.1, AP002001.2, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29.
- chr13:46,125,920–46,298,110, 7 genes, copy number 3: LCP1, RN7SL288P, LRRC63, RN7SKP5, ABITRAMP1, AL139801.1, LINC00563.
- chr13:74,828,553–75,606,020, 9 genes, copy number 4 (within-gene range 2–4): RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3.
- chr14:70,187,123–71,928,596, 45 genes, copy number 3 (within-gene range 2–3): AL160191.1, AL160191.3, AL160191.2, ADAM21P1, AL356804.1, COX16, SYNJ2BP-COX16, RNU2-51P, SYNJ2BP, AL357153.2, ADAM21, ADAM20P1, RNU6-659P, ADAM20, AL357153.4, MED6, AL357153.3, KRT18P7, AL357153.1, RN7SL77P, TTC9, LINC01269, MAP3K9, AC004816.1, AC004816.2, AC004825.1, AC004825.2, PCNX1, AC004825.3, AC005230.1, GTF3AP2, PTTG4P, AC004817.3, AC004817.5, AC004817.2, AC004817.1, AC004817.4, AC005476.2, SIPA1L1, AC005476.1, SNORD56B, RN7SL683P, AC004974.1, AC004900.1, AC005993.1.
- chr17:63,819,433–83,240,804, 633 genes, copy number 3–6 (broad region; genes not listed).
- chr19:5,558,167–6,433,779, 49 genes, copy number 3: TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1, RFX2, AC011444.2, AC011444.4, AC011444.3, ACSBG2, AC011471.1, AC011471.4, MLLT1, AC011471.2, AC011471.3, ACER1, AC011491.3, CLPP, ALKBH7, PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1, KHSRP, MIR3940, SLC25A41.
- chr20:7,633,562–8,999,100, 13 genes, copy number 3: RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 24,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
